Somatic mutation profile of tumor specimen MMRF_2813_1_BM_CD138pos (aliquot MMRF_2813_1_BM_CD138pos_T1_KHS5U_L15699) from MMRF case MMRF_2813, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.9 years (20,034 days).
Specimen MMRF_2813_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bef46fd9-8203-41b4-96c5-e569456cb000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2813_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2813_1_PB_WBC_C3_KHS5U_L15745; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/491128c7-b293-459c-b78e-944caaa24846

The open-access MAF lists 48 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 15, Intron 5, Silent 4, Frame Shift Del 3, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, RNA 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs773909937, COSV62754978, COSV62755085; called by muse, mutect2, varscan2
- CFAP74 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 62/66 reads (94%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs370699074, COSV54564266; called by muse, mutect2, varscan2
- DLGAP1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs376007911; called by muse, mutect2, varscan2
- FBXL7 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 116/281 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1356248686, COSV61641264; called by muse, mutect2, varscan2
- IGHV2-70 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 130/134 reads (97%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs372630587; called by muse, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 134/139 reads (96%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, varscan2
- PRDM1 | c.550T>G p.F184V | Missense Mutation (SNP) | VAF 108/121 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99057957; called by muse, mutect2, varscan2
- EOMES | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- KAT6A | c.1019dup p.N340Kfs*25 | Frame Shift Ins (INS) | VAF 272/462 reads (59%) | called by pindel, varscan2
- KIF3B | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXL1 | c.471_505del p.V158Afs*123 | Frame Shift Del (DEL) | VAF 61/154 reads (40%) | called by mutect2, pindel
- MXD4 | c.146_150delinsC p.R49Pfs*12 | Frame Shift Del (DEL) | VAF 40/45 reads (89%) | called by pindel, varscan2*
- MYH10 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 248/257 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFE2L2 | c.59_62del p.I20Tfs*8 | Frame Shift Del (DEL) | VAF 135/169 reads (80%) | called by pindel, varscan2
- PCLO | c.13763+2_13763+3del p.X4588_splice | Splice Site (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- PCLO | c.717A>G p.I239M | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PGBD4 | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 209/504 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RC3H1 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 213/223 reads (96%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1403C>T p.S468L (on ENST00000621492; = p.S434L on NM_025248.3) | Missense Mutation (SNP) | VAF 63/63 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TUSC2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT3A2 | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CAV3 | c.249A>G p.P83= | Silent (SNP) | VAF 89/214 reads (42%) | called by muse, mutect2, varscan2
- CSMD3 | c.3927T>G p.A1309= (on ENST00000297405 / NM_001363185.1; = p.A1205= on NM_052900.3) | Silent (SNP) | VAF 165/177 reads (93%) | catalogued as rs1412675743; called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>C p.L101= | Silent (SNP) | VAF 66/137 reads (48%) | catalogued as rs1421187044; called by muse, mutect2, varscan2
- TIGD5 | c.768G>A p.P256= | Silent (SNP) | VAF 54/55 reads (98%) | called by muse, mutect2, varscan2
- AGXT2 | c.*41G>T | 3'UTR (SNP) | VAF 107/271 reads (39%) | called by muse, mutect2, varscan2
- ARL14EP | c.*777A>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, varscan2
- ARL14EP | c.*848_*849insG | 3'UTR (INS) | VAF 20/56 reads (36%) | called by pindel, varscan2
- CAV1 | c.*1216G>A | 3'UTR (SNP) | VAF 69/126 reads (55%) | called by muse, mutect2, varscan2
- CTBP1 | c.195+147A>C | Intron (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460099 C>A | 3'Flank (SNP) | VAF 6/48 reads (13%) | catalogued as rs774630781; called by muse, varscan2
- F9 | c.*1289G>A | 3'UTR (SNP) | VAF 50/52 reads (96%) | called by muse, mutect2, varscan2
- GNL1 | c.*4134T>G | 3'UTR (SNP) | VAF 87/95 reads (92%) | called by muse, mutect2, varscan2
- GNPDA1 | c.-6-254T>G | Intron (SNP) | VAF 82/164 reads (50%) | called by muse, mutect2, varscan2
- GPC5 | c.*334C>A | 3'UTR (SNP) | VAF 46/54 reads (85%) | called by muse, mutect2, varscan2
- IL6R | c.*1514G>T | 3'UTR (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- MYL12A | c.-15-930C>T | Intron (SNP) | VAF 120/262 reads (46%) | called by muse, mutect2, varscan2
- MYO1E | c.-126T>C | 5'UTR (SNP) | VAF 80/182 reads (44%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.55G>A | RNA (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- NSD1 | c.*63C>G | 3'UTR (SNP) | VAF 116/233 reads (50%) | called by muse, mutect2, varscan2
- PAX6 | c.11-1465C>T | Intron (SNP) | VAF 80/194 reads (41%) | called by muse, mutect2, varscan2
- PGBD4 | c.*80G>A | 3'UTR (SNP) | VAF 102/233 reads (44%) | catalogued as rs769515401; called by muse, mutect2, varscan2
- RUFY3 | c.*608C>T | 3'UTR (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- STOM | c.*234T>G | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- TCF21 | c.*1049T>C | 3'UTR (SNP) | VAF 73/81 reads (90%) | catalogued as rs1054342239, COSV52818454; called by muse, mutect2, varscan2
- UTP3 | c.*119A>C | 3'UTR (SNP) | VAF 48/49 reads (98%) | called by muse, mutect2, varscan2
- WNT7B | c.*385G>A | 3'UTR (SNP) | VAF 65/74 reads (88%) | catalogued as rs1252739817; called by muse, mutect2, varscan2
- ZNF195 | c.226+4006C>T | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as rs1351350397; called by muse, mutect2, varscan2
